Somatic mutation profile of tumor specimen MBCProject_1197_T1_WES (aliquot MBCProject_1197_T1_WES_1) from CMI case MBCProject_1197, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 32.8 years (11,998 days).
Specimen MBCProject_1197_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2413103-814e-43e6-a1f7-f6a2742b6106.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1197_SALIVA (Saliva), aliquot MBCProject_1197_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4deebfb7-f248-4f71-943b-3d24385751da

The open-access MAF lists 40 somatic variants for this specimen: 24 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 12, Intron 2, Frame Shift Del 2, RNA 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 364/454 reads (80%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASTN2 | c.3463A>G p.I1155V (on ENST00000313400 / NM_001365069.1; = p.I1104V on NM_014010.5) | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs1233919920; called by muse, mutect2, varscan2
- BBOF1 | c.1480del p.Q494Kfs*40 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as COSV63247400; called by mutect2, pindel
- HUWE1 | c.10510C>T p.P3504S | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs199693166; called by muse, mutect2, varscan2
- KLHL35 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 94/3500 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs1431920189; called by muse, mutect2
- LRRC8A | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV52184457; called by muse, mutect2, varscan2
- MROH8 | c.1107T>A p.F369L | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1254017053; called by muse, mutect2, varscan2
- PLEKHM3 | c.1855C>G p.R619G | Missense Mutation (SNP) | VAF 62/654 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV101216846, COSV66817608; called by muse, mutect2
- PNCK | c.197G>A p.R66H (on ENST00000340888 / NM_001366975.1; = p.R149H on NM_001039582.3) | Missense Mutation (SNP) | VAF 81/375 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs782395857, COSV61744122; called by muse, mutect2, varscan2
- RNF169 | c.1983G>C p.Q661H | Missense Mutation (SNP) | VAF 81/546 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV55132442; called by muse, mutect2, varscan2
- SSC4D | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 168/836 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV51881134; called by muse, mutect2, varscan2
- TP53 | c.277dup p.L93Pfs*56 | Frame Shift Ins (INS) | VAF 93/348 reads (27%) | catalogued as COSV53026854, COSV53780326; called by mutect2, pindel, varscan2
- TRPA1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 54/845 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1418337572, COSV51558783; called by muse, mutect2
- DHX34 | c.3335C>T p.T1112I | Missense Mutation (SNP) | VAF 115/583 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNMBP | c.3682G>T p.V1228F | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- FAM47E-STBD1 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 110/606 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- IL34 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 73/377 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- INTS6 | c.223A>G p.N75D | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- MAP3K15 | c.2206G>A p.A736T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- MRPL27 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2
- OSMR | c.1991T>C p.L664P | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PLCB2 | c.1265A>G p.E422G | Missense Mutation (SNP) | VAF 60/374 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SIRPB2 | c.896_902del p.L299Qfs*32 | Frame Shift Del (DEL) | VAF 47/292 reads (16%) | called by pindel, varscan2
- TRAPPC8 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABHD12B | c.1041C>A p.P347= (on ENST00000337334 / NM_001206673.2; = p.P270= on NM_181533.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- CELSR1 | c.4248C>T p.G1416= | Silent (SNP) | VAF 64/708 reads (9%) | catalogued as rs1351233917; called by muse, mutect2
- GSTA5 | c.36A>T p.A12= | Silent (SNP) | VAF 53/240 reads (22%) | called by muse, mutect2, varscan2
- HDAC6 | c.1956C>T p.H652= | Silent (SNP) | VAF 37/402 reads (9%) | catalogued as rs368341039; ClinVar: likely benign; called by muse, mutect2
- KISS1R | c.786G>A p.S262= | Silent (SNP) | VAF 44/505 reads (9%) | catalogued as rs1449859608; called by muse, mutect2
- LATS2 | c.1053G>A p.S351= | Silent (SNP) | VAF 49/150 reads (33%) | called by muse, mutect2, varscan2
- MIA2 | c.666G>A p.Q222= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as rs768641844; called by muse, mutect2, varscan2
- NRXN1 | c.192C>T p.R64= | Silent (SNP) | VAF 48/275 reads (17%) | catalogued as rs748944452, COSV68004234; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ROBO1 | c.1392G>A p.Q464= | Silent (SNP) | VAF 46/186 reads (25%) | called by muse, mutect2, varscan2
- SCN11A | c.882G>A p.P294= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as rs761791422, COSV56568277, COSV56569488; ClinVar: likely benign; called by muse, mutect2
- SIRPB2 | c.888C>T p.V296= | Silent (SNP) | VAF 46/234 reads (20%) | called by muse, varscan2
- SLC66A2 | c.66C>T p.A22= | Silent (SNP) | VAF 44/898 reads (5%) | called by muse, mutect2
- REV3L | c.9043-618T>A | Intron (SNP) | VAF 8/57 reads (14%) | catalogued as rs1356395055; called by muse, varscan2
- TBC1D3P2 | n.529G>A | RNA (SNP) | VAF 68/510 reads (13%) | catalogued as rs766717430; called by muse, mutect2, varscan2
- TMEM249 | c.528+30C>T | Intron (SNP) | VAF 124/655 reads (19%) | catalogued as rs1554852057; called by muse, mutect2, varscan2
- TTC3P1 | n.5516C>T | RNA (SNP) | VAF 59/398 reads (15%) | called by muse, mutect2, varscan2
